Surgical pathology report (de-identified scan), TCGA case TCGA-PJ-A8JU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Gundersen Lutheran, specimen TCGA-PJ-A8JU-01A (Primary Tumor).

[page 1 of 2]
Patient:

Med. Record. No.:

Date of Birth:

Submitted by:

Report also to:

Age:

Sex: F

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

DIAGNOSIS:

SPECIMEN

Right radical nephrectomy

TUMOR

Histologic type: Papillary renal cell carcinoma

Histologic grade (Fuhrman nuclear grade): Grade 2

Focality: Solitary within specimen

Tumor size (greatest dimension): 3.5cm

Extent of direct tumor invasion: No direct extension beyond kidney

Sarcomatoid component: Absent

Lymphovascular invasion (excluding renal vein): Absent

Renal vein involvement: Absent

Pathologic findings in non-neoplastic kidney:

No additional significant pathologic findings

Adrenal: Not present

MARGINS

All margins negative for carcinoma

LYMPH NODES

Cannot be assessed

STAGING (AJCC)

Primary Tumor: pT1a

Lymph Nodes: pNX

Distant Metastasis: Not applicable

ICD-O-3

Carcinoma, papillary renal cell 8260/3

Site: @ Kidney NOS C64.9

JW 1/29/14

CLINICAL INFORMATION:

Right renal mass.

SPECIMEN(S) RECEIVED:

Right kidney

[page 2 of 2]
Patient: [REDACTED]

MRN: [REDACTED]

GROSS DESCRIPTION:

Received fresh is a 643 gram radical nephrectomy which consists of a 9 x 6.5 x 5.5 cm kidney and surrounding perinephric fat, 0.8 to 6 cm. An adrenal gland is not submitted with the specimen. Located centrally in the mid pole of the kidney is a soft, nodular, well-circumscribed 3.5 x 3 x 2.5 cm dark red to red-yellow mass. The lesion compresses the renal pelvis but does not grossly appear to invade into it. The lesion grossly comes to within 0.1 cm of the cortical surface and to within 0.6 cm of Gerota's fascia which is inked. Sectioning through the rest of the kidney reveals glistening, unremarkable maroon-gray parenchyma with cortical thickness measuring 0.6 to 1.1 cm. Dissection of the ureter and vessels at the renal hilum reveals patent lumina with no gross evidence of tumor invasion. Representative sections are submitted as follows: A1 – ureter and blood vessels margins; A2 – A4 – mass with adjacent normal kidney and renal pelvis; A5 – mass with inked Gerota's fascia; A6 – normal kidney.

Slides were microscopically examined by the pathologist.

Evaluation performed by [REDACTED]

Electronically signed [REDACTED]

Pathology Report

Prior Malignancy History	NO TX	✓
Dual/Synchronous Primary Neoplasms	QUALIFIED	DISQUALIFIED

Source: NCI Genomic Data Commons file 248664a4-a64e-4e11-b250-12a087c6de51 (TCGA-PJ-A8JU.6F1D0DF7-40E0-453A-B5A1-240C90EED5C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).